Somatic mutation profile of tumor specimen TARGET-10-PARVEI-09A (aliquot TARGET-10-PARVEI-09A-01D) from TARGET case TARGET-10-PARVEI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,253 days).
Specimen TARGET-10-PARVEI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fa1e833-c940-4b1d-aaaa-100766bde52d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARVEI-10A (Blood Derived Normal), aliquot TARGET-10-PARVEI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42361491-693d-4547-8bf3-e47ab4dc5935

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Ins 4, Intron 2, Splice Region 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH13 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs375168918; called by muse, varscan2
- CRMP1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs373508403, COSV61481822; called by muse, mutect2, varscan2
- EPAS1 | c.2216_2217insTC p.M740Rfs*2 | Frame Shift Ins (INS) | VAF 32/91 reads (35%) | catalogued as COSV55386596; called by mutect2, pindel, varscan2
- FNDC3B | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 59/133 reads (44%) | catalogued as COSV61037308, COSV61041242; called by muse, mutect2, varscan2
- GATA2 | c.1077A>C p.L359F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62004486; called by muse, mutect2, varscan2
- GPRIN2 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV65401037; called by muse, mutect2, varscan2
- GRXCR2 | c.695G>T p.C232F | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65061159; called by muse, mutect2, varscan2
- HECTD4 | c.9185C>T p.P3062L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348349656, COSV66390854, COSV66392995; called by muse, mutect2, varscan2
- MED12 | c.111_112insAGACCG p.T37_A38insRP | In Frame Ins (INS) | VAF 10/32 reads (31%) | catalogued as COSV61349102; called by mutect2, varscan2
- NACAD | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775826435, COSV71989483; called by muse, mutect2, varscan2
- NOTCH1 | c.5027T>A p.V1676D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53026269; called by muse, mutect2, varscan2
- OR14C36 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV58600374; called by muse, mutect2, varscan2
- OR4Q3 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV59178700; called by muse, mutect2, varscan2
- PIEZO2 | c.4778C>T p.A1593V | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.985); catalogued as COSV57439905; called by muse, mutect2, varscan2
- POLRMT | c.2536G>C p.V846L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV52114759; called by muse, mutect2, varscan2
- TNN | c.2622C>A p.S874R | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53426488; called by muse, mutect2, varscan2
- BAHCC1 | c.6606dup p.T2203Dfs*16 | Frame Shift Ins (INS) | VAF 21/40 reads (53%) | called by mutect2, varscan2
- PLEKHG2 | c.3735dup p.S1246Lfs*16 | Frame Shift Ins (INS) | VAF 45/104 reads (43%) | called by mutect2, pindel, varscan2
- ROBO2 | c.1680C>T p.F560= | Splice Region (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- SPEN | c.6313dup p.A2105Gfs*18 | Frame Shift Ins (INS) | VAF 42/112 reads (38%) | called by pindel, varscan2
- BARHL2 | c.21C>T p.S7= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV64981335; called by muse, mutect2, varscan2
- DNAI2 | c.1698C>T p.D566= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs142710343; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSF5 | c.306G>C p.P102= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs1375599792; called by muse, varscan2
- ITPR3 | c.6486C>T p.D2162= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs772497157, COSV65405982; called by muse, mutect2, varscan2
- NTF3 | c.762C>T p.I254= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as rs201630054, COSV58417125; called by muse, mutect2, varscan2
- SCNN1B | c.552T>C p.C184= | Silent (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1904+105G>T | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- MALRD1 | c.4688-205C>T | Intron (SNP) | VAF 51/121 reads (42%) | catalogued as rs917430184; called by muse, mutect2, varscan2
